Surgical pathology report (de-identified scan), TCGA case TCGA-BP-4158, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-4158-01A (Primary Tumor).

[page 1 of 2]
CGA-BP-4158

Other Related Data:

Billing Type: [REDACTED]
Financial Number: [REDACTED]

Clinical Diagnosis & History:

Metastatic workup for recently diagnosed prostate cancer;
incidental finding of right renal mass.

Specimens Submitted:

1: SP: Right kidney [REDACTED]
2: SP: Paracaval lymph nodes [REDACTED]

DIAGNOSIS:

- 1) KIDNEY, RIGHT; NEPHRECTOMY:
- RENAL CELL CARCINOMA, CLEAR CELL TYPE, NUCLEAR GRADE II/IV. THE PATTERN OF GROWTH IS ACINAR. THE TUMOR'S GREATEST DIAMETER IS 7.0 CM.
- THE TUMOR IS CONFINED WITHIN THE RENAL CAPSULE.
- VASCULAR INVASION IS IDENTIFIED.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.
- THE NON-NEOPLASTIC KIDNEY IS UNREMARKABLE.
- THE ADRENAL GLAND IS NOT SUBMITTED.
- 2) LYMPH NODES, PARACAVAL; EXCISION:
- FIVE LYMPH NODES, NEGATIVE FOR CARCINOMA (0/5).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]

Gross Description:

1) The specimen is received fresh, labeled "Right Kidney". It consists of nephrectomy specimen entirely measuring 23.13 x 0.5 cm and weighing 700 gm. The kidney measures 12.5 x 7.5 x 0.5 cm after stripping fat and weighs 280 gm. A 11 cm segment of ureter is identified. A well-circumscribed yellow, focally hyalinized, tumor is present towards the upper pole measuring 0.7 x 5.8 cm. There is no necrosis identified within tumor. It

[page 2 of 2]
seems to be grossly confined within the renal capsule and bulges into the renal pelvis. There is no invasion of renal vein grossly. The kidney away from the tumor appears unremarkable.

Summary of Sections:

T - tumor
TC - tumor with HILUM
TK - tumor with sounding kidney
TP - tumor with pelvis
K - kidney away from tumor
STM - soft tissue margin
UM - ureteric margin
VM - vascular margin
FAD - perinephritic fat
ADD - tumor with capsule

2) The specimen is received in formalin, labeled, "Paracaval Lymph Nodes". It consists of fatty tissue measuring 5.0 x 4.0 x 2.0 cm in aggregate. Multiple lymph nodes are identified, with the largest measuring 2.5 cm. All lymph nodes identified are submitted.

Summary of Sections:

BI - one bisected lymph node in two cassettes
LNB - bisected lymph nodes
LN - multiple lymph nodes

Summary of Sections:

Part	Sect.	Site	Blocks	Pieces	All
1	ADD		1	M	
	FAT		2	M	
	K		1	M	
	STM		1	M	
	T		4	M	
	TC		1	M	
	TK		1	M	
	TP		1	M	
	UM		1	M	
	VM		1	M	
2	BI		2	M	
	LN		1	M	
	LNB		1	M	

Source: NCI Genomic Data Commons file f5adb68a-b72c-4c51-9453-51d965cac2d0 (TCGA-BP-4158.DABBAFC2-35C3-4044-9C09-8C54B9D81B93.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).